Somatic mutation profile of tumor specimen TCGA-YU-A90P-01A (aliquot TCGA-YU-A90P-01A-11D-A435-10) from TCGA case TCGA-YU-A90P, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 25.0 years (9,144 days).
Specimen TCGA-YU-A90P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c79b801-5104-49ea-b04c-705c1df88244.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YU-A90P-10A (Blood Derived Normal), aliquot TCGA-YU-A90P-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8acaab4-6d1a-41df-8e5a-50eb6fd433a2

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs782691184, COSV53995547; called by muse, mutect2, varscan2
- ANKRD30B | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.537); catalogued as rs372583134; called by muse, mutect2, varscan2
- PROX1 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV54778577; called by muse, mutect2
- RBP1 | c.130G>C p.V44L (on ENST00000619087 / NM_001365940.2; = p.V106L on NM_002899.5) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51677964; called by muse, mutect2
- TRIM23 | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV51550838; called by muse, mutect2, varscan2
- USH2A | c.13484G>A p.R4495H | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs550096037, COSV56370194; called by muse, mutect2, varscan2
- PCDH7 | c.2072C>T p.T691M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGPD4 | c.5064G>C p.K1688N | Missense Mutation (SNP) | VAF 36/772 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); called by muse, mutect2
- HNRNPM | c.1098G>C p.G366= | Silent (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- MSH5 | c.1020G>C p.V340= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- TPP2 | chr13:102596996 del CAGCCTGGCAGTTTGCCGCTTCCT | 5'UTR (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
